Somatic mutation profile of tumor specimen TCGA-DA-A1IC-06A (aliquot TCGA-DA-A1IC-06A-11D-A197-08) from TCGA case TCGA-DA-A1IC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 86.9 years (31,728 days).
Specimen TCGA-DA-A1IC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acea4706-d3fe-4e98-9bbf-c336a7145743.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1IC-10A (Blood Derived Normal), aliquot TCGA-DA-A1IC-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65876ebf-2bd3-4629-9692-fa9a29266371

The open-access MAF lists 1,200 somatic variants for this specimen: 770 protein-altering or splice-affecting, 406 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 698, Silent 406, Nonsense Mutation 49, RNA 14, Splice Site 13, Intron 7, Splice Region 4, Frame Shift Del 4, Translation Start Site 1, 5'UTR 1, In Frame Del 1, 3'Flank 1.

Variants (750 of 1,200; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, varscan2
- PDPK1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 51/102 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1263044277, COSV51913046; called by muse, mutect2, varscan2
- PDPK1 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 51/106 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51913098; called by muse, mutect2, varscan2
- A2ML1 | c.1422T>A p.Y474* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as COSV55297767; called by muse, mutect2, varscan2
- AATK | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV58692328; called by muse, mutect2, varscan2
- ABCB9 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV54894030; called by muse, mutect2, varscan2
- ABCC9 | c.2775G>A p.M925I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53984409; called by muse, mutect2, varscan2
- ACAA1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776632031, COSV57179750; called by muse, mutect2
- ACAN | c.7100G>A p.G2367D (on ENST00000560601 / NM_001369268.1; = p.G2291D on NM_001135.3) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs780006455, COSV61368468; called by muse, mutect2, varscan2
- ACLY | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV61252779; called by muse, mutect2, varscan2
- ACSL6 | c.1829C>T p.S610F (on ENST00000379240; = p.S635F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV57296784, COSV57296958; called by muse, mutect2, varscan2
- ACSM1 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1257838041, COSV54639665; called by muse, mutect2, varscan2
- ACSM3 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs768023499, COSV56846841; called by muse, mutect2
- ACSM5 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV59374521; called by muse, mutect2, varscan2
- ADAM10 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1433624874, COSV53054551; called by muse, mutect2, varscan2
- ADAM21 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99961247; called by muse, mutect2
- ADAM33 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1464577794, COSV62936775; called by muse, mutect2, varscan2
- ADAMTS14 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV64605973; called by muse, mutect2, varscan2
- ADAMTS18 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865821391, COSV51410950; called by muse, mutect2, varscan2
- ADAMTS19 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201713825, COSV50731649; called by muse, mutect2, varscan2
- ADAMTS19 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.485); catalogued as rs749189377, COSV50793162; called by muse, mutect2, varscan2
- ADAMTS20 | c.3062C>T p.S1021F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs751029124, COSV67131471; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs775366242, COSV65899206; called by muse, mutect2, varscan2
- ADGRG6 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV51591113, COSV51600282; called by muse, mutect2, varscan2
- ADGRV1 | c.3356G>C p.G1119A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67994362; called by muse, mutect2, varscan2
- ADGRV1 | c.16502C>T p.S5501F | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs866464814, COSV67980225; called by muse, mutect2, varscan2
- AFF1 | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57120891, COSV57123594; called by muse, mutect2, varscan2
- AGTR1 | c.753T>A p.F251L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV62559996; called by muse, mutect2, varscan2
- AKAP10 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV56732948; called by muse, mutect2, varscan2
- AKNA | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV56314744; called by muse, mutect2, varscan2
- ALDOB | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as rs867022678, COSV66397306; called by muse, mutect2, varscan2
- ALK | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66586154; called by muse, mutect2, varscan2
- ALOX12B | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV59875903; called by muse, mutect2, varscan2
- ALPK2 | c.4847G>A p.G1616E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV64492252; called by muse, mutect2, varscan2
- AMDHD2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1406321097, COSV53552240; called by muse, mutect2, varscan2
- AMER3 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.421); catalogued as COSV100366039, COSV58469766; called by muse, mutect2, varscan2
- ANK2 | c.7756G>A p.E2586K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52185604; called by muse, mutect2, varscan2
- ANO4 | c.2063G>A p.R688K (on ENST00000392977 / NM_001286615.2; = p.R653K on NM_178826.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs761072068, COSV54593473; called by muse, mutect2, varscan2
- APBA2 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as COSV68794887; called by muse, mutect2, varscan2
- APCDD1 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.161); catalogued as COSV62373301; called by muse, mutect2, varscan2
- APOL1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs1027205673, COSV59869189; called by muse, mutect2, varscan2
- AQP4 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV67219336; called by muse, mutect2, varscan2
- ARAP2 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58291578; called by muse, mutect2, varscan2
- ARHGAP29 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53116311; called by muse, mutect2, varscan2
- ARHGAP44 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV52401704; called by muse, mutect2, varscan2
- ARHGAP6 | c.2197G>A p.D733N (on ENST00000337414 / NM_013427.3; = p.D530N on NM_013423.3) | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771155355, COSV57292292; called by muse, mutect2, varscan2
- ARHGEF3 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as rs539002604, COSV56331952; called by muse, mutect2, varscan2
- ARID1A | c.3961C>T p.P1321S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774283518, COSV61375481; called by muse, mutect2, varscan2
- ARID2 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 40/92 reads (43%) | catalogued as COSV57595998; called by muse, mutect2, varscan2
- ARID5B | c.1051A>T p.N351Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54428870; called by muse, mutect2, varscan2
- ARPP21 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs1356078676, COSV51804101; called by muse, mutect2, varscan2
- ASAH2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 94/282 reads (33%) | catalogued as rs1413048671; called by muse, mutect2, varscan2
- ASAH2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs777210243, COSV61483878; called by muse, mutect2, varscan2
- ASIC2 | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV56769572; called by muse, mutect2, varscan2
- ASPSCR1 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1362769025, COSV60715921, COSV60716381; called by muse, mutect2, varscan2
- ASTL | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV100668412; called by muse, mutect2, varscan2
- ASTN1 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1485620000, COSV56081808; called by muse, mutect2, varscan2
- ATG2A | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65968725; called by muse, mutect2, varscan2
- ATIC | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs750765780, COSV52695227; called by muse, mutect2, varscan2
- ATL3 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as COSV100219939; called by muse, mutect2, varscan2
- ATP11B | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60030349; called by muse, mutect2, varscan2
- ATP11C | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV59573187; called by muse, mutect2, varscan2
- ATP13A1 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754809322, COSV52290899; called by muse, mutect2, varscan2
- AXL | c.1379C>T p.A460V (on ENST00000301178 / NM_021913.5; = p.A451V on NM_001699.6) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.686); catalogued as COSV56574097; called by muse, mutect2, varscan2
- B4GALNT2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV55928067; called by muse, mutect2, varscan2
- B4GALNT3 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56757475; called by muse, mutect2, varscan2
- BAZ1A | c.4508C>T p.S1503L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1389574742, COSV62409622; called by muse, mutect2, varscan2
- BIK | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV51793564; called by muse, mutect2, varscan2
- BMP2 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66579274; called by muse, mutect2, varscan2
- BNIPL | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 48/221 reads (22%) | catalogued as COSV54845779, COSV54848742; called by muse, varscan2
- BPIFB4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV64950602; called by muse, mutect2, varscan2
- BTNL8 | c.223T>A p.F75I | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.223); catalogued as COSV51461481; called by muse, mutect2, varscan2
- C1R | c.1832G>A p.G611E (on ENST00000536053 / NM_001354346.2; = p.G597E on NM_001733.7) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101605634; called by muse, mutect2, varscan2
- C1S | c.849G>A p.W283* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV61072254; called by muse, mutect2, varscan2
- C1orf87 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs762612884, COSV64596931; called by muse, mutect2, varscan2
- C2CD2 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs1351453525, COSV61600409; called by muse, mutect2, varscan2
- C6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV54714318; called by muse, mutect2, varscan2
- C7orf31 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs774467136, COSV52216009; called by muse, mutect2, varscan2
- C8A | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1483234568, COSV63484731; called by muse, mutect2, varscan2
- C8B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 43/85 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV64779451; called by muse, mutect2, varscan2
- CACNA1D | c.5204C>T p.S1735L (on ENST00000350061 / NM_001128840.3; = p.S1755L on NM_000720.4) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1461261149, COSV55437928; called by muse, mutect2, varscan2
- CACNA1F | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs782263474, COSV59906778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV60817644; called by muse, mutect2, varscan2
- CALB2 | c.262-1G>A p.X88_splice | Splice Site (SNP) | VAF 29/83 reads (35%) | catalogued as COSV56941981; called by muse, mutect2, varscan2
- CASC3 | c.14G>C p.R5P | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52869177; called by muse, varscan2
- CATSPERB | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV56423836; called by muse, mutect2, varscan2
- CCDC33 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58357286; called by muse, mutect2, varscan2
- CCDC33 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.332); catalogued as COSV51503098, COSV51503553; called by mutect2, varscan2
- CCL2 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56773971; called by muse, varscan2
- CCND1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs746088878, COSV57119961, COSV57121002; called by muse, mutect2, varscan2
- CCNE1 | c.881T>C p.F294S | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52905658; called by muse, mutect2, varscan2
- CCNJ | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56444438; called by muse, mutect2, varscan2
- CCNT2 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51476379; called by muse, mutect2, varscan2
- CCR9 | c.1093G>A p.G365R (on ENST00000357632 / NM_031200.3; = p.G353R on NM_006641.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV62940236; called by muse, mutect2, varscan2
- CCR9 | c.1094G>A p.G365E (on ENST00000357632 / NM_031200.3; = p.G353E on NM_006641.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV100591737; called by muse, mutect2, varscan2
- CCT6A | c.236A>T p.K79M | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99303623; called by muse, mutect2, varscan2
- CD3D | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.8); PolyPhen benign (0.018); catalogued as COSV52676061; called by muse, mutect2, varscan2
- CD86 | c.269C>T p.S90L (on ENST00000330540 / NM_175862.5; = p.S84L on NM_006889.4) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs761419249, COSV52609967; called by muse, mutect2, varscan2
- CDH10 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV52568255; called by muse, mutect2, varscan2
- CDH4 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV64672789, COSV64673235; called by muse, mutect2, varscan2
- CDK3 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV56915300; called by muse, mutect2, varscan2
- CDKN2C | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52955842; called by muse, mutect2, varscan2
- CELSR1 | c.5495C>T p.S1832F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV53099000; called by muse, mutect2, varscan2
- CELSR3 | c.8732C>T p.S2911L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99374294; called by muse, mutect2, varscan2
- CEMIP2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 27/42 reads (64%) | catalogued as rs746389869, COSV65488164; called by muse, mutect2, varscan2
- CENPE | c.5353G>A p.E1785K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as COSV54378601, COSV54389100; called by muse, mutect2, varscan2
- CENPE | c.2601+2T>C p.X867_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as COSV54389118; called by muse, mutect2, varscan2
- CEP250 | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs150723097; called by muse, mutect2, varscan2
- CERKL | c.1223G>A p.G408E (on ENST00000339098 / NM_001030311.2; = p.G382E on NM_201548.5) | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs776211842, COSV59211628; called by muse, mutect2, varscan2
- CFHR2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as COSV66380777; called by muse, mutect2, varscan2
- CFHR2 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100804366; called by muse, varscan2
- CFHR3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100807594, COSV66403215; called by muse, mutect2, varscan2
- CFHR3 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1160905862, COSV66403218; called by muse, mutect2, varscan2
- CHML | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59367188; called by muse, mutect2, varscan2
- CHST5 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1241792912, COSV60341326; called by muse, mutect2, varscan2
- CILP | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.803); catalogued as rs769904740, COSV56025127; called by muse, mutect2, varscan2
- CIP2A | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV55421134; called by muse, mutect2, varscan2
- CLDN22 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100032968; called by muse, mutect2, varscan2
- CLIP4 | c.650A>T p.N217I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60752360; called by muse, mutect2, varscan2
- CLN6 | c.827G>A p.W276* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | catalogued as COSV51118105; called by muse, mutect2, varscan2
- CLVS2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.328); catalogued as COSV51565713; called by muse, mutect2, varscan2
- CMYA5 | c.11007G>A p.M3669I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV71409162; called by muse, mutect2, varscan2
- CNN3 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs891411357, COSV64637535; called by muse, mutect2, varscan2
- CNTN1 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV61638603, COSV61645039; called by muse, varscan2
- CNTNAP4 | c.3833G>A p.R1278K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.142); catalogued as COSV56698422; called by muse, mutect2, varscan2
- COL19A1 | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59586802; called by muse, mutect2, varscan2
- COL20A1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as rs779300811, COSV58921492; called by muse, mutect2, varscan2
- COL22A1 | c.4516G>A p.G1506R | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357790; called by muse, mutect2, varscan2
- COPB2 | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV60351182; called by muse, mutect2
- CORIN | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56690547; called by muse, mutect2, varscan2
- CORIN | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV56699006; called by muse, mutect2, varscan2
- CORIN | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); catalogued as rs547405481, COSV99904057; called by muse, mutect2, varscan2
- CPAMD8 | c.4168G>A p.D1390N (on ENST00000651564; = p.D1343N on NM_015692.5) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV71597335; called by muse, mutect2
- CPNE6 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV53743098; called by muse, mutect2, varscan2
- CPNE9 | c.635A>C p.N212T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV56069740; called by muse, mutect2, varscan2
- CPT1B | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56418862; called by muse, mutect2, varscan2
- CRB1 | c.3823A>C p.T1275P | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs551798394, COSV100957994; called by muse, mutect2, varscan2
- CRB1 | c.3824C>A p.T1275K | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100957996; called by muse, mutect2, varscan2
- CRIM1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54871657; called by muse, mutect2, varscan2
- CRNN | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55123646; called by muse, mutect2, varscan2
- CRP | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 111/644 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV54814539; called by muse, mutect2, varscan2
- CRYBG2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV57489579; called by muse, mutect2, varscan2
- CRYBG2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV57489583; called by muse, mutect2, varscan2
- CSF2RA | c.452T>A p.F151Y | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV100817853; called by muse, mutect2, varscan2
- CSF2RA | c.453T>A p.F151L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100817854; called by muse, mutect2, varscan2
- CSF2RB | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV53260694; called by muse, mutect2, varscan2
- CSMD1 | c.9569G>A p.G3190E (on ENST00000520002; = p.G3189E on NM_033225.6) | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243591838, COSV59377198; called by muse, mutect2, varscan2
- CSMD1 | c.8086G>A p.G2696S (on ENST00000520002; = p.G2695S on NM_033225.6) | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV59377219; called by muse, mutect2, varscan2
- CSMD2 | c.2785C>T p.Q929* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV53957024; called by muse, mutect2, varscan2
- CTNND2 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.708); catalogued as COSV58923818; called by muse, mutect2, varscan2
- CYP21A2 | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 77/383 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64488078; called by muse, mutect2, varscan2
- CYP2A13 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1314003584, COSV57839874; called by muse, mutect2, varscan2
- CYP4B1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV54725940, COSV99597552; called by muse, mutect2, varscan2
- CYP4F11 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV56125495; called by muse, mutect2, varscan2
- CYP4F22 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54111486; called by muse, mutect2, varscan2
- DAB2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1200956898, COSV57913581; called by muse, mutect2, varscan2
- DAO | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.396); catalogued as COSV57324398; called by muse, mutect2, varscan2
- DAPP1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV56453463; called by muse, mutect2, varscan2
- DBNDD2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376511192; called by muse, mutect2, varscan2
- DCAF16 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV66384373; called by muse, mutect2, varscan2
- DCAF8L1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1195330470, COSV71595215; called by muse, mutect2, varscan2
- DCDC1 | c.2035T>A p.F679I | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV60857105; called by muse, mutect2, varscan2
- DCN | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs1394663371, COSV50009091; called by muse, mutect2, varscan2
- DDN | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV60294569; called by muse, mutect2
- DDX18 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV54308963; called by muse, mutect2, varscan2
- DDX25 | c.1321A>G p.K441E | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as rs1565468794, COSV54992461; called by muse, mutect2, varscan2
- DDX60 | c.1228T>A p.Y410N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV67098981; called by muse, mutect2, varscan2
- DENND1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57568717; called by muse, mutect2, varscan2
- DENND3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 88/115 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377080240; called by muse, mutect2, varscan2
- DENND5B | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV60907844; called by muse, mutect2, varscan2
- DGKD | c.1861C>T p.R621C (on ENST00000264057 / NM_152879.3; = p.R577C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1010742705, COSV51050032; called by muse, mutect2, varscan2
- DHRS1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV55385643; called by muse, mutect2, varscan2
- DHRSX | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.17); catalogued as rs778932498, COSV100585846; called by muse, mutect2, varscan2
- DHX15 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61025627; called by muse, mutect2, varscan2
- DHX57 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as COSV54890625; called by muse, mutect2, varscan2
- DKK2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as COSV53402958; called by muse, mutect2, varscan2
- DMPK | c.337-1G>A p.X113_splice | Splice Site (SNP) | VAF 31/107 reads (29%) | catalogued as COSV52180011; called by muse, mutect2, varscan2
- DNAAF6 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV60495142; called by muse, mutect2, varscan2
- DNAH11 | c.5063C>A p.P1688Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV60978408; called by muse, mutect2, varscan2
- DNAH2 | c.4417T>A p.F1473I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66726248; called by muse, mutect2, varscan2
- DNAH5 | c.10750G>A p.D3584N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54210354; called by muse, mutect2, varscan2
- DNAH5 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54230014; called by muse, mutect2, varscan2
- DNAH7 | c.8281C>T p.P2761S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV56783424; called by muse, mutect2, varscan2
- DNAH8 | c.2342T>C p.I781T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV59477033; called by muse, mutect2, varscan2
- DNAJB5 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV56626453; called by muse, mutect2, varscan2
- DOCK1 | c.4457A>C p.E1486A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as rs571507465, COSV54757964; called by mutect2, varscan2
- DSCAML1 | c.2969C>T p.S990F (on ENST00000321322; = p.S930F on NM_020693.4) | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1465069433, COSV58394347; called by muse, mutect2, varscan2
- DSG3 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57124281; called by muse, mutect2, varscan2
- DSG4 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV57387632; called by muse, mutect2, varscan2
- DUOX2 | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772609489, COSV66532966; called by muse, mutect2, varscan2
- DUS3L | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs144731277; called by muse, mutect2, varscan2
- DUSP22 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as rs1469443817, COSV60530939; called by muse, varscan2
- DYRK3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as rs782758295, COSV65607793; called by muse, mutect2, varscan2
- EBF3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs867491601, COSV62473339; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs773883186, COSV62570646; called by muse, mutect2, varscan2
- EFTUD2 | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as rs1287272854, COSV53656167; called by muse, mutect2, varscan2
- EIF4G3 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51692832; called by muse, mutect2, varscan2
- ELAC2 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV52401710; called by muse, mutect2, varscan2
- EMILIN2 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1342752494, COSV54427101; called by muse, mutect2, varscan2
- ENPEP | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54456825; called by muse, mutect2, varscan2
- EPHA10 | c.2762C>T p.P921L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV57626965; called by muse, mutect2, varscan2
- EPHB3 | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374567246; called by muse, mutect2, varscan2
- ERAP2 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411675424, COSV65941272; called by muse, mutect2, varscan2
- ESRRG | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs866478481, COSV63173762; called by muse, mutect2, varscan2
- ETS2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV62874224; called by muse, mutect2, varscan2
- EVC2 | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1157866730, COSV60401689; called by muse, mutect2, varscan2
- EVPL | c.4951C>T p.Q1651* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV56915311; called by muse, mutect2, varscan2
- EYA3 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV65817617; called by muse, mutect2, varscan2
- FAM126B | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs779731390, COSV53774984; called by muse, mutect2, varscan2
- FAM131C | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767524464; called by muse, varscan2
- FAM135A | c.715C>T p.R239C (on ENST00000370479 / NM_001351599.1; = p.R196C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs376512666, COSV52058425; called by muse, mutect2, varscan2
- FAM193A | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs774644793, COSV61198263; called by muse, mutect2, varscan2
- FAM227B | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV54818624; called by muse, mutect2, varscan2
- FAM83B | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV60926370; called by muse, mutect2, varscan2
- FAT3 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 492/632 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53167604; called by muse, mutect2, varscan2
- FAT3 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 399/548 reads (73%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV53167654; called by muse, varscan2
- FBXW10 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as COSV57321927; called by muse, mutect2, varscan2
- FCN1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs199881741; called by muse, mutect2, varscan2
- FCRL5 | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV62511879, COSV62512606; called by muse, mutect2, varscan2
- FCRL5 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs767516344, COSV62512924; called by muse, mutect2, varscan2
- FCRL6 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs752905425, COSV58942534; called by muse, mutect2, varscan2
- FDX2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV53348378; called by muse, mutect2, varscan2
- FER1L6 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.238); catalogued as rs149657957; called by muse, varscan2
- FER1L6 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.573); catalogued as COSV67552563; called by muse, mutect2, varscan2
- FETUB | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV54007057; called by muse, mutect2, varscan2
- FGF21 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs374311260, COSV55809980; called by muse, mutect2, varscan2
- FGL2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1402782011, COSV50385132; called by muse, mutect2, varscan2
- FLG2 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 42/256 reads (16%) | catalogued as COSV66166972; called by muse, mutect2, varscan2
- FMNL2 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.023); catalogued as COSV56503521; called by muse, mutect2, varscan2
- FRY | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100969612; called by muse, mutect2, varscan2
- FSCB | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.729); catalogued as COSV61219183; called by muse, mutect2, varscan2
- FST | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV56816755; called by muse, mutect2, varscan2
- FTSJ3 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as COSV59563880; called by muse, mutect2, varscan2
- FYB2 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as rs866866257, COSV58585657; called by muse, mutect2, varscan2
- GABRE | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99059200; called by muse, mutect2, varscan2
- GABRR3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760476762, COSV72084269; called by muse, mutect2, varscan2
- GALNT5 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs866363296, COSV52040900; called by muse, mutect2, varscan2
- GAMT | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52041161; called by muse, mutect2, varscan2
- GAPT | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59247343; called by muse, mutect2, varscan2
- GBP3 | c.77A>T p.E26V | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52519863; called by muse, mutect2, varscan2
- GDF5 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1568731539, COSV65500368; called by muse, mutect2, varscan2
- GEMIN5 | c.2809C>T p.Q937* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV53564381; called by muse, mutect2, varscan2
- GHR | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV50128790; called by muse, mutect2, varscan2
- GINS4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV52532120; called by muse, mutect2, varscan2
- GJA8 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782429592, COSV53790475; called by muse, mutect2, varscan2
- GPD1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56549043; called by muse, mutect2, varscan2
- GPD1L | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56992187; called by muse, mutect2, varscan2
- GPR142 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.19); catalogued as COSV100170903; called by muse, mutect2, varscan2
- GPR142 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV59519152; called by muse, mutect2, varscan2
- GPR158 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as COSV66272607; called by muse, mutect2, varscan2
- GPR18 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV61621493; called by muse, mutect2, varscan2
- GPX6 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV62658895; called by muse, mutect2, varscan2
- GRAMD2B | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as COSV53509884; called by muse, mutect2, varscan2
- GRIA1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV53603871; called by muse, mutect2, varscan2
- GRIA3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 87/97 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52047488, COSV52078860; called by muse, mutect2, varscan2
- GRID2 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs550165966, COSV56188977; called by muse, mutect2, varscan2
- GRIN3A | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs867334369, COSV62450515; called by muse, mutect2, varscan2
- GRM5 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV59626754; called by muse, mutect2, varscan2
- GRWD1 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775372217, COSV53520586; called by muse, mutect2, varscan2
- GSAP | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs781616360, COSV57532845; called by muse, mutect2, varscan2
- GXYLT2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.102); catalogued as COSV67475094; called by muse, mutect2, varscan2
- GYPA | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV51636726; called by muse, mutect2, varscan2
- HCN3 | c.1585T>C p.F529L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV61362449; called by muse, mutect2, varscan2
- HDAC7 | c.2200G>A p.D734N (on ENST00000427332; = p.D773N on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs759760258, COSV50407371; called by muse, mutect2, varscan2
- HELQ | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV55027629; called by muse, mutect2, varscan2
- HGFAC | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV66977103; called by muse, mutect2, varscan2
- HLA-DMB | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV66870733; called by muse, mutect2, varscan2
- HNF4A | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV57384322; called by muse, mutect2, varscan2
- HNF4A | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.218); catalogued as COSV57387010, COSV57388724; called by muse, mutect2, varscan2
- HOXB1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs1474149158, COSV53318570; called by muse, mutect2, varscan2
- HRNR | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs201506455, COSV64261722, COSV64262317; called by muse, mutect2, varscan2
- HSD17B2 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs766233863, COSV52278355; called by muse, mutect2, varscan2
- HSF1 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV60049176; called by muse, mutect2, varscan2
- HSF1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60049185; called by muse, mutect2, varscan2
- HSPA12B | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV54768902; called by muse, mutect2, varscan2
- HSPG2 | c.5048C>T p.P1683L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65976777; called by muse, mutect2, varscan2
- HTR3C | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs201399376; called by muse, mutect2, varscan2
- HTR4 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV58803771; called by muse, mutect2, varscan2
- IGHV3-15 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782559388; called by muse, mutect2, varscan2
- IGHV3-53 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1212388099; called by muse, mutect2, varscan2
- IGKV3-11 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs1420052809; called by muse, mutect2, varscan2
- IGLV3-9 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs747589489; called by muse, mutect2, varscan2
- IGSF1 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 75/89 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63840011; called by muse, mutect2, varscan2
- IGSF10 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56791069; called by muse, mutect2, varscan2
- IL1RL1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as rs201523855, COSV52112555; called by muse, mutect2, varscan2
- IL27RA | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as rs200164865, COSV54602927; called by muse, varscan2
- INAVA | c.328T>A p.S110T | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.891); catalogued as COSV66257431; called by muse, mutect2, varscan2
- ING4 | c.553G>A p.D185N (on ENST00000396807 / NM_001127582.2; = p.D184N on NM_016162.4) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs1353710889, COSV57525236; called by muse, mutect2, varscan2
- INTS9 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 64/90 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV68433843, COSV68435723; called by muse, mutect2, varscan2
- ISM2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV53635260; called by muse, mutect2, varscan2
- ITFG2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV57390984; called by muse, mutect2, varscan2
- ITGA4 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1315003450, COSV51998379; called by muse, mutect2, varscan2
- ITGAM | c.2797C>T p.H933Y (on ENST00000648685 / NM_001145808.2; = p.H932Y on NM_000632.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs1255766887, COSV99792783; called by muse, mutect2, varscan2
- ITGAM | c.3061G>A p.V1021M (on ENST00000648685 / NM_001145808.2; = p.V1020M on NM_000632.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99792786; called by muse, mutect2, varscan2
- ITGB7 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770990025, COSV57240255; called by muse, varscan2
- ITIH5 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs763021116, COSV53660271, COSV53661373; called by muse, mutect2, varscan2
- ITK | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 181/500 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68435465; called by muse, mutect2, varscan2
- ITLN1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1444675320, COSV58275151; called by muse, mutect2, varscan2
- JADE2 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV50930292; called by muse, mutect2, varscan2
- JARID2 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as rs749941345, COSV59197141; called by muse, mutect2, varscan2
- JCAD | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1174543513, COSV64761484; called by muse, varscan2
- KCND3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.062); catalogued as rs764928165, COSV56188774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778103101, COSV51132178; called by muse, mutect2, varscan2
- KCNH2 | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs199473514, CM097828, COSV51127133; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNH7 | c.2597G>A p.R866K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV59807171, COSV59811974; called by muse, mutect2, varscan2
- KCNK2 | c.822A>G p.A274= (on ENST00000444842 / NM_001017425.3; = p.A259= on NM_014217.4) | Splice Region (SNP) | VAF 29/139 reads (21%) | catalogued as COSV67209820; called by muse, mutect2, varscan2
- KCNT2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV54106327; called by muse, mutect2, varscan2
- KCTD20 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.386); catalogued as rs759819629, COSV54804650; called by muse, mutect2, varscan2
- KDM5C | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64769138; called by muse, mutect2, varscan2
- KDR | c.3565G>A p.D1189N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV55773238; called by muse, mutect2, varscan2
- KIAA1549 | c.5417C>T p.S1806L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV54324744; called by muse, mutect2
- KIAA1549 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765861143, COSV54326983; called by muse, mutect2, varscan2
- KIF13B | c.3377G>A p.R1126H | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778861935, COSV72954682; called by muse, mutect2, varscan2
- KIF6 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV54692689; called by muse, mutect2, varscan2
- KIR2DL1 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as COSV52415322; called by muse, mutect2, varscan2
- KLHL23 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55867081; called by muse, mutect2, varscan2
- KLHL4 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV64147357; called by muse, mutect2, varscan2
- KLHL40 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as rs771551921, COSV55137120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT38 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs371518902; called by muse, mutect2, varscan2
- KRT6A | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV58107557; called by muse, mutect2, varscan2
- KRT6B | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs746866169, COSV52883144; called by muse, mutect2, varscan2
- KRTAP5-2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 136/171 reads (80%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.172); catalogued as COSV69014782; called by muse, mutect2, varscan2
- LAMA5 | c.4726C>T p.P1576S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV53371290; called by muse, mutect2, varscan2
- LCE2A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 103/183 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs112496497, COSV64227127; called by muse, mutect2, varscan2
- LGALS3BP | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs1461262648, COSV53166012; called by muse, mutect2, varscan2
- LILRA2 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV52196350; called by muse, mutect2, varscan2
- LIMA1 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV57968242; called by muse, mutect2, varscan2
- LRFN1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1023018556, COSV50501112; called by muse, mutect2, varscan2
- LRIF1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63897606, COSV63898369; called by muse, mutect2, varscan2
- LRP1 | c.1531A>G p.S511G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as COSV54524572; called by muse, mutect2, varscan2
- LRP1B | c.8599G>A p.G2867R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67269710; called by muse, mutect2, varscan2
- LRP1B | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV67269714; called by muse, mutect2, varscan2
- LRP2 | c.8848G>A p.D2950N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55571531, COSV99789023; called by muse, mutect2, varscan2
- LRRC37A3 | c.4580T>G p.L1527R | Missense Mutation (SNP) | VAF 108/417 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58537020; called by muse, mutect2, varscan2
- LRRC37B | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100496393; called by muse, varscan2
- LRRC3B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs1447656470, COSV67519995; called by muse, mutect2, varscan2
- LRRC61 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as COSV56232067; called by muse, mutect2, varscan2
- LRRC8E | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907395826, COSV60719209; called by muse, mutect2, varscan2
- LRRIQ1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67837634; called by muse, mutect2, varscan2
- LRRIQ3 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV63049407; called by muse, mutect2, varscan2
- MAB21L4 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.104); catalogued as rs200160556, COSV100278460; called by muse, mutect2, varscan2
- MACROH2A1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56897830; called by muse, mutect2, varscan2
- MAGEB6 | c.637A>T p.K213* | Nonsense Mutation (SNP) | VAF 55/64 reads (86%) | catalogued as COSV66873004; called by muse, mutect2, varscan2
- MAK | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57567528; called by muse, mutect2, varscan2
- MAN1C1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1371141247, COSV56043615, COSV56044783; called by muse, mutect2, varscan2
- MAP2 | c.99T>G p.D33E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.022); catalogued as COSV52306301; called by muse, mutect2, varscan2
- MAP2 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV52306321; called by muse, mutect2, varscan2
- MAP3K15 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 207/253 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370641677, COSV58837517; called by muse, mutect2, varscan2
- MAP3K21 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as COSV64042485; called by muse, mutect2, varscan2
- MARCHF2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV53106617; called by muse, mutect2, varscan2
- MARCO | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs201982149, COSV59055315; called by muse, mutect2, varscan2
- MARK1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV65070968; called by muse, mutect2, varscan2
- MARVELD3 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.536); catalogued as COSV99194847; called by muse, mutect2
- MAST2 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.597); catalogued as COSV63621246; called by muse, mutect2, varscan2
- MAST4 | c.5374G>A p.G1792S (on ENST00000403625 / NM_001164664.2; = p.G1603S on NM_015183.3) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV99844997; called by muse, mutect2, varscan2
- MAST4 | c.5375G>A p.G1792D (on ENST00000403625 / NM_001164664.2; = p.G1603D on NM_015183.3) | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99845005; called by muse, mutect2, varscan2
- MCM2 | c.1500C>A p.F500L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54033243, COSV54037018; called by muse, mutect2, varscan2
- MCUR1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs760715136, COSV100848966; called by muse, mutect2, varscan2
- MECR | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs772261961, COSV55287293; called by muse, mutect2, varscan2
- MEGF11 | c.2487G>A p.M829I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV56560173; called by muse, mutect2, varscan2
- MET | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV100577311; called by muse, varscan2
- MFAP2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.194); catalogued as COSV65004070; called by muse, mutect2, varscan2
- MICAL3 | c.886A>C p.T296P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52904684; called by muse, mutect2, varscan2
- MIDEAS | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs552919914, COSV54098494; called by muse, mutect2, varscan2
- MMP28 | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as rs1555604280; called by muse, mutect2, varscan2
- MPP7 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as rs868850825, COSV61730067; called by muse, varscan2
- MPRIP | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs531558875, COSV57929473; called by muse, mutect2, varscan2
- MPST | c.431C>T p.S144F (on ENST00000341116 / NM_001369904.2; = p.S164F on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV62018621; called by muse, mutect2, varscan2
- MROH2B | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs755657335, COSV68189022; called by muse, mutect2, varscan2
- MROH2B | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.912); catalogued as rs866591320, COSV68189034; called by muse, mutect2, varscan2
- MROH7 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV59876159; called by muse, mutect2, varscan2
- MSRB3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV57597187; called by muse, mutect2, varscan2
- MUC16 | c.40037G>A p.R13346K | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.455); catalogued as COSV66696052; called by muse, mutect2, varscan2
- MUC16 | c.28922C>T p.S9641F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV67490283; called by muse, mutect2, varscan2
- MUC16 | c.26654C>T p.S8885F | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67490291; called by muse, mutect2, varscan2
- MUC16 | c.8515G>A p.A2839T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV67474863; called by muse, mutect2, varscan2
- MUC16 | c.8185C>T p.P2729S | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV67490318; called by muse, mutect2, varscan2
- MUC17 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 372/822 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs781393959, COSV60302110; called by muse, mutect2, varscan2
- MUC4 | c.13546G>A p.E4516K (on ENST00000463781 / NM_018406.7; = p.E280K on NM_004532.6) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as rs200291819, COSV57782456; called by muse, mutect2, varscan2
- MUC7 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV59219369, COSV59220029; called by muse, mutect2, varscan2
- MUL1 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as COSV51643193; called by muse, mutect2, varscan2
- MVP | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372484922; called by muse, mutect2, varscan2
- MYCBP2 | c.11299C>T p.L3767F (on ENST00000357337; = p.L3805F on NM_015057.5) | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV62037435; called by muse, mutect2, varscan2
- MYH14 | c.5026C>T p.R1676W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761720529, COSV51829987; called by muse, mutect2, varscan2
- MYH4 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1395341095, COSV55125350; called by muse, mutect2, varscan2
- MYH6 | c.2603C>T p.S868F | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147015593, COSV62454145; called by muse, mutect2, varscan2
- MYO15A | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs767388755, COSV52751423; called by muse, mutect2, varscan2
- MYO18A | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62872763; called by muse, mutect2, varscan2
- MYO18B | c.6277G>A p.D2093N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.385); catalogued as COSV59147163; called by muse, mutect2, varscan2
- MYO3A | c.2380A>G p.S794G | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1265874854, COSV56347077; called by muse, mutect2, varscan2
- MYOCD | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV58511286; called by muse, mutect2, varscan2
- MYOG | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99614011; called by muse, mutect2, varscan2
- MYOM3 | c.2657A>G p.Q886R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV58400306; called by muse, varscan2
- NBAS | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55736432; called by muse, mutect2, varscan2
- NCOA3 | c.3928C>T p.P1310S (on ENST00000371998 / NM_181659.3; = p.P1306S on NM_006534.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV59072934; called by muse, mutect2, varscan2
- NCOR1 | c.4340G>A p.R1447Q | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375150524; called by muse, mutect2, varscan2
- NDUFA10 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53156435; called by muse, mutect2, varscan2
- NDUFAB1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV50287640; called by muse, mutect2, varscan2
- NDUFAF1 | c.760-1G>A p.X254_splice | Splice Site (SNP) | VAF 13/52 reads (25%) | catalogued as COSV52976333; called by muse, mutect2, varscan2
- NDUFS4 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57018980; called by muse, mutect2, varscan2
- NEDD1 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV57146534; called by muse, mutect2, varscan2
- NEUROG3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54343774; called by muse, mutect2, varscan2
- NF1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as CM961025, COSV62197350; called by muse, mutect2, varscan2
- NF1 | c.2087G>A p.W696* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as CM1311461, COSV62219374; called by muse, mutect2, varscan2
- NFXL1 | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV61200610; called by muse, mutect2, varscan2
- NGF | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101049613; called by muse, mutect2, varscan2
- NIPBL | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV56964291; called by muse, mutect2, varscan2
- NLGN1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV64345481; called by muse, mutect2, varscan2
- NLRP10 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 86/113 reads (76%) | SIFT tolerated (0.54); PolyPhen benign (0.109); catalogued as COSV60778693; called by muse, mutect2, varscan2
- NLRP11 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.082); catalogued as rs937856777, COSV64088669; called by muse, mutect2, varscan2
- NLRP3 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100276347, COSV60228184; called by muse, mutect2, varscan2
- NLRP4 | c.2282A>G p.N761S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.788); catalogued as COSV56722283; called by muse, mutect2, varscan2
- NLRP5 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV66767111; called by muse, mutect2, varscan2
- NOBOX | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV56197432; called by muse, mutect2, varscan2
- NOS3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV99871923; called by mutect2, varscan2
- NOTCH2 | c.173T>A p.L58* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99865555; called by mutect2, varscan2
- NPTXR | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60729522; called by muse, mutect2, varscan2
- NRAP | c.5063G>A p.R1688K (on ENST00000359988 / NM_001322945.2; = p.R1653K on NM_006175.4) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as COSV100668017; called by muse, mutect2, varscan2
- NRAP | c.571-1G>A p.X191_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV63493622; called by muse, mutect2, varscan2
- NRK | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 40/52 reads (77%) | catalogued as COSV54605689; called by muse, mutect2, varscan2
- NUB1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63427569; called by muse, mutect2, varscan2
- NUP214 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as COSV63908607; called by muse, mutect2, varscan2
- NYNRIN | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV66844795; called by muse, mutect2, varscan2
- OPN4 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54119341; called by muse, mutect2, varscan2
- OPRL1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61092788; called by muse, mutect2, varscan2
- OR10A6 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.59); PolyPhen benign (0.076); catalogued as rs1046759192, COSV59164631; called by muse, mutect2, varscan2
- OR2T2 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.87); catalogued as COSV100737691, COSV61618957; called by muse, mutect2, varscan2
- OR2T34 | c.550T>G p.C184G | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170453, COSV60900349; called by muse, mutect2, varscan2
- OR4D2 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV73459867; called by muse, varscan2
- OR4D2 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV73459868; called by muse, varscan2
- OR4F15 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); catalogued as COSV59969706, COSV59970191; called by muse, mutect2, varscan2
- OR4M1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60059391; called by muse, mutect2, varscan2
- OR52I2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 144/211 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV57046031; called by muse, mutect2, varscan2
- OR52N4 | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 94/129 reads (73%) | catalogued as COSV57892864; called by muse, mutect2, varscan2
- OR8B4 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62069607, COSV62070511; called by muse, mutect2, varscan2
- OTOS | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV56228896; called by muse, mutect2, varscan2
- OTUD5 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1370200083, COSV50238960; called by muse, mutect2, varscan2
- OTUD7A | c.1934C>T p.A645V (on ENST00000307050 / NM_001382637.1; = p.A638V on NM_130901.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.592); catalogued as rs759299434, COSV100192851; called by muse, mutect2
- P2RX4 | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV58742410, COSV58742770; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.410C>T p.A137V (on ENST00000374531 / NM_001037293.2; = p.A169V on NM_053016.6) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV57131354; called by muse, mutect2, varscan2
- PAN3 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.094); catalogued as COSV66710921; called by muse, mutect2, varscan2
- PANX3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52513691, COSV52514334; called by muse, varscan2
- PAPLN | c.3361G>A p.D1121N (on ENST00000554301; = p.D1094N on NM_173462.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1231306630, COSV53723013; called by muse, mutect2, varscan2
- PAPPA | c.4789C>T p.P1597S | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV60290855; called by muse, mutect2, varscan2
- PARD3B | c.3557A>T p.D1186V (on ENST00000406610 / NM_001302769.2; = p.D1117V on NM_057177.7) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs372978414; called by muse, mutect2, varscan2
- PCDHA4 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as rs782455168, COSV63538631; called by muse, mutect2, varscan2
- PCDHB12 | c.832T>A p.S278T | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as COSV53400592; called by muse, mutect2, varscan2
- PCDHB13 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99507559; called by muse, mutect2, varscan2
- PCDHB2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52031260; called by muse, mutect2, varscan2
- PCDHB9 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); catalogued as COSV53383330; called by muse, mutect2, varscan2
- PCDHGA11 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54021999; called by muse, mutect2, varscan2
- PCDHGA6 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs769494929, COSV54021949; called by muse, mutect2, varscan2
- PCDHGA8 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV53940288; called by muse, mutect2, varscan2
- PCGF3 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs779253635, COSV62860790; called by muse, mutect2, varscan2
- PCLO | c.7457T>C p.V2486A | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV61662629; called by muse, mutect2, varscan2
- PCLO | c.5459G>A p.R1820K | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61643950, COSV61662642; called by muse, mutect2, varscan2
- PCLO | c.5212G>A p.D1738N | Missense Mutation (SNP) | VAF 120/283 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61662651; called by muse, mutect2, varscan2
- PCLO | c.4861G>A p.E1621K | Missense Mutation (SNP) | VAF 251/614 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1257458794, COSV61634547; called by muse, mutect2, varscan2
- PCNT | c.3338G>A p.S1113N | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs763212290, COSV64032714; called by muse, mutect2, varscan2
- PCSK2 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs756030433, COSV52734637; called by muse, mutect2, varscan2
- PCSK2 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52742275; called by muse, mutect2, varscan2
- PCSK2 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV52725663, COSV52742339; called by muse, mutect2, varscan2
- PCSK5 | c.1102A>T p.K368* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as COSV65095772; called by muse, mutect2
- PCSK5 | c.2198-1G>A p.X733_splice | Splice Site (SNP) | VAF 13/18 reads (72%) | catalogued as COSV65095788; called by muse, mutect2, varscan2
- PCSK7 | c.1851G>A p.W617* | Nonsense Mutation (SNP) | VAF 46/103 reads (45%) | catalogued as COSV99639138; called by muse, mutect2, varscan2
- PCTP | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs778064181, COSV52122495; called by muse, mutect2, varscan2
- PDE1A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs145482728, COSV59527650; called by muse, mutect2, varscan2
- PDE1C | c.1268T>A p.V423D | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58527156; called by muse, mutect2, varscan2
- PDE4D | c.493C>T p.P165S (on ENST00000340635 / NM_001104631.2; = p.P29S on NM_006203.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); catalogued as rs756389970, COSV58977294; called by muse, mutect2, varscan2
- PDE6C | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs148611776; called by muse, mutect2, varscan2
- PDGFD | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs751185406, COSV56392685; called by muse, mutect2, varscan2
- PDGFRB | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV55809683; called by muse, mutect2, varscan2
- PDIA4 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs777967052, COSV99618724; called by muse, mutect2, varscan2
- PDXDC1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57911519; called by muse, mutect2, varscan2
- PEG10 | c.178G>A p.E60K (on ENST00000482108 / NM_001040152.2; = p.E94K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV71788653, COSV71788812; called by muse, mutect2, varscan2
- PEG3 | c.3634C>T p.R1212C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1452885066, COSV55645813; called by muse, mutect2, varscan2
- PHRF1 | c.3800C>T p.A1267V (on ENST00000264555 / NM_001286581.2; = p.A1266V on NM_020901.4) | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.234); catalogued as COSV99212709; called by muse, mutect2, varscan2
- PHTF1 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV63368758; called by muse, mutect2, varscan2
- PI4KB | c.437C>T p.S146L (on ENST00000368873 / NM_001369623.1; = p.S158L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV55020766; called by muse, mutect2, varscan2
- PIGU | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV54166057; called by muse, mutect2, varscan2
- PIK3C2G | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as COSV56831054, COSV56841486; called by muse, mutect2, varscan2
- PIK3CG | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100782413, COSV63252935; called by muse, mutect2, varscan2
- PIK3CG | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs775602332, COSV63252944; called by muse, mutect2, varscan2
- PIPOX | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as rs1428880697, COSV60143547; called by muse, mutect2, varscan2
- PKD2L1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58395783; called by muse, mutect2, varscan2
- PLA2G4F | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.82); catalogued as rs945569470, COSV51827487; called by muse, mutect2, varscan2
- PLEC | c.3391C>G p.L1131V (on ENST00000322810 / NM_201380.4; = p.L1021V on NM_000445.5) | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59691143; called by muse, mutect2, varscan2
- PLEK | c.924G>C p.K308N | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as COSV52252700, COSV52253785; called by muse, mutect2, varscan2
- PLEKHG4B | c.3341G>A p.R1114K (on ENST00000283426; = p.R1470K on NM_052909.5) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769648412, COSV52046023; called by muse, mutect2, varscan2
- PM20D1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV65649578; called by muse, mutect2, varscan2
- PMEPA1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55696184; called by muse, mutect2, varscan2
- POLR2B | c.2979G>C p.K993N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.593); catalogued as COSV58901769, COSV58902432; called by muse, mutect2
- POM121L12 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs764722281, COSV68692179; called by muse, mutect2, varscan2
- POTED | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55049326; called by muse, mutect2, varscan2
- POTEE | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58242870; called by muse, mutect2, varscan2
- POU2F2 | c.614A>G p.Q205R (on ENST00000526816 / NM_001207025.3; = p.Q189R on NM_002698.5) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60766400; called by muse, mutect2, varscan2
- PRAMEF18 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as rs1469898981; called by muse, mutect2, varscan2
- PRKCB | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57798359; called by muse, mutect2
- PRKCE | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.074); catalogued as rs373332822; called by muse, mutect2, varscan2
- PRKG2 | c.1083C>T p.I361= | Splice Region (SNP) | VAF 32/113 reads (28%) | catalogued as COSV52331190; called by muse, mutect2, varscan2
- PROX2 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV71520167; called by muse, mutect2, varscan2
- PRPF40B | c.49C>T p.P17S (on ENST00000380281; = p.P11S on NM_012272.3) | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); catalogued as COSV56061589; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1099C>T p.P367S (on ENST00000352766; = p.P288S on NM_181334.5) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1569163145, COSV100424506; called by muse, mutect2, varscan2
- PRRC2A | c.4910C>T p.P1637L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV52992934; called by muse, mutect2, varscan2
- PRRC2C | c.1258C>T p.P420S (on ENST00000367742; = p.P418S on NM_015172.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV58912258; called by muse, mutect2, varscan2
- PRUNE2 | c.3985G>A p.E1329K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV65047191; called by muse, mutect2, varscan2
- PRXL2B | c.715C>T p.P239S (on ENST00000444521; = p.P191S on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV56525866; called by muse, mutect2, varscan2
- PTF1A | c.76T>A p.F26I | Missense Mutation (SNP) | VAF 125/337 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100919598; called by muse, mutect2, varscan2
- PTF1A | c.77T>C p.F26S | Missense Mutation (SNP) | VAF 129/340 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100919599; called by muse, mutect2, varscan2
- PTGIS | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs201288052, COSV54839484, COSV54840323; called by muse, mutect2, varscan2
- PTH1R | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57317617; called by muse, mutect2, varscan2
- PTPN18 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV51560618; called by muse, mutect2, varscan2
- PTPN9 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs751709167, COSV60725379; called by muse, mutect2, varscan2
- PTPRS | c.4261C>T p.R1421C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440179947, COSV53632784; called by muse, mutect2, varscan2
- R3HDM1 | c.2264T>C p.F755S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV51532225; called by muse, mutect2, varscan2
- RAB19 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs568276754, COSV52045883; called by muse, mutect2, varscan2
- RASA2 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53945695; called by muse, mutect2, varscan2
- RASA3 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs751128700, COSV61864215; called by muse, mutect2, varscan2
- RBM5 | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100762427, COSV61738881; called by muse, mutect2, varscan2
- REEP5 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV54844063; called by muse, mutect2, varscan2
- REN | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV65817674, COSV65817736; called by muse, mutect2, varscan2
- RFX1 | c.371C>G p.T124S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); catalogued as COSV99586274; called by muse, mutect2, varscan2
- RHOT1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs765050930, COSV61718174; called by muse, mutect2
- RNF157 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs769015834, COSV53947961; called by muse, mutect2, varscan2
- ROBO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs754092395, COSV71394997, COSV71396072; called by muse, mutect2, varscan2
- ROCK1 | c.3793C>T p.H1265Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67699086; called by muse, mutect2, varscan2
- ROR1 | c.164-1G>A p.X55_splice | Splice Site (SNP) | VAF 40/101 reads (40%) | catalogued as COSV64292675; called by muse, mutect2, varscan2
- RP1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV55117626; called by muse, mutect2, varscan2
- RP1L1 | c.7009G>A p.E2337K | Missense Mutation (SNP) | VAF 145/200 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV66759714; called by muse, mutect2, varscan2
- RPAP1 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV58541847; called by muse, mutect2, varscan2
- RPGR | c.2903A>C p.K968T (on ENST00000339363 / NM_001367249.1; = p.K763T on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV58839658; called by muse, mutect2, varscan2
- RPGRIP1 | c.2237G>A p.G746E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61751268, CM012461, COSV52856465; ClinVar: not provided; called by muse, mutect2, varscan2
- RPH3A | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as COSV101231857; called by muse, varscan2
- RPH3A | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as COSV66990962; called by muse, varscan2
- RSL1D1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV63077450; called by muse, mutect2, varscan2
- RSPO3 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as rs1231073114, COSV63152909; called by muse, mutect2, varscan2
- RTN4 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58273407; called by muse, mutect2, varscan2
- RXFP3 | c.1076T>A p.F359Y | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs776735601, COSV57508012; called by muse, mutect2, varscan2
- RYR1 | c.12460C>T p.P4154S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62109519; called by muse, mutect2, varscan2
- SALL1 | c.3839G>A p.G1280E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51764037; called by muse, varscan2
- SALL1 | c.3773G>A p.G1258D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51764047; called by muse, varscan2
- SALL1 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51764058; called by muse, mutect2, varscan2
- SALL1 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as COSV51758332, COSV51764066; called by muse, mutect2, varscan2
- SALL2 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.415); catalogued as rs1319600456, COSV58105641; called by muse, mutect2, varscan2
- SCAF4 | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs767263244, COSV54591731; called by muse, mutect2, varscan2
- SCAMP5 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); catalogued as COSV62644132; called by muse, mutect2, varscan2
- SCGB1D4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 204/256 reads (80%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV62204384; called by muse, mutect2, varscan2
- SCN10A | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs200714519; called by muse, mutect2, varscan2
- SCN11A | c.5083G>A p.G1695S | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413143057, COSV56571336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV57671564; called by muse, mutect2, varscan2
- SDE2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs771107418, COSV55253062; called by muse, mutect2, varscan2
- SENP3 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV53437758; called by muse, mutect2, varscan2
- SENP7 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs775229337, COSV58618211; called by muse, mutect2, varscan2
- SEPTIN5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63531006; called by muse, mutect2, varscan2
- SERPINB13 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV54030762; called by muse, mutect2, varscan2
- SERPINI2 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV52988609; called by muse, mutect2, varscan2
- SETD5 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV56716891; called by muse, mutect2, varscan2
- SEZ6L | c.2212+1G>A p.X738_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | catalogued as COSV50683612; called by muse, mutect2, varscan2
- SF3B3 | c.2432C>G p.T811R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as COSV56790832; called by muse, mutect2, varscan2
- SF3B4 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV54964683; called by muse, mutect2, varscan2
- SH3PXD2A | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1176333434, COSV100583979, COSV63509838; called by muse, mutect2, varscan2
- SH3TC2 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV60467454; called by muse, mutect2, varscan2
- SHC1 | c.1030C>T p.P344S (on ENST00000368445 / NM_183001.5; = p.P234S on NM_003029.5) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV63535140; called by muse, mutect2, varscan2
- SHE | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV100496126; called by muse, mutect2, varscan2
- SHOC2 | c.1519A>T p.T507S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV54624396; called by muse, mutect2, varscan2
- SIGLEC5 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV55783604; called by muse, mutect2, varscan2
- SIM2 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs201356831, COSV51772544; called by muse, mutect2, varscan2
- SKIDA1 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs749987100, COSV71611135; called by muse, mutect2, varscan2
- SKIDA1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as rs1358894648, COSV101481329; called by muse, mutect2, varscan2
- SLC10A6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV56720754; called by muse, mutect2, varscan2
- SLC10A6 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99907336; called by muse, mutect2, varscan2
- SLC14A2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54914079; called by muse, mutect2
- SLC15A2 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55200642; called by muse, mutect2, varscan2
- SLC15A2 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs754293562, COSV55197574, COSV55200651; called by muse, mutect2, varscan2
- SLC16A5 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.07); catalogued as rs149877409; called by muse, mutect2, varscan2
- SLC17A3 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs200308750; called by muse, mutect2, varscan2
- SLC25A13 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.477); catalogued as COSV55713004; called by muse, mutect2, varscan2
- SLC26A1 | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV68311275; called by muse, mutect2, varscan2
- SLC26A6 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs767256137, COSV56573305; called by muse, mutect2, varscan2
- SLC2A11 | c.290C>T p.S97F (on ENST00000345044 / NM_001024938.4; = p.S104F on NM_030807.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1315264068, COSV55391163, COSV55393790; called by muse, mutect2, varscan2
- SLC35B1 | c.389C>T p.S130F (on ENST00000649906; = p.S93F on NM_005827.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV53604141; called by muse, mutect2, varscan2
- SLC38A4 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs866526000, COSV56966841; called by muse, mutect2, varscan2
- SLC46A3 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV57184296; called by muse, mutect2, varscan2
- SLC52A3 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV54079129; called by muse, mutect2, varscan2
- SLC5A12 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV68451058; called by muse, mutect2, varscan2
- SLC5A8 | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV73311163; called by muse, mutect2, varscan2
- SLC6A13 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58260071; called by muse, mutect2, varscan2
- SLC6A17 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58996464; called by muse, mutect2, varscan2
- SLC7A4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs759867735; called by muse, mutect2
- SLC9A4 | c.1925G>A p.G642D | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV54838700; called by muse, mutect2, varscan2
- SLC9C2 | c.1049T>G p.L350W | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV62948992, COSV62949869; called by muse, mutect2, varscan2
- SLC9C2 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62948995; called by muse, mutect2, varscan2
- SLCO1B1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57016231; called by muse, mutect2, varscan2
- SLCO1B3 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53943410; called by muse, mutect2, varscan2
- SLCO1B3 | c.1544G>A p.R515K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV53934447, COSV53937619; called by muse, mutect2, varscan2
- SLCO6A1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs868787940, COSV65805866; called by muse, mutect2, varscan2
- SLITRK3 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV53852955; called by muse, mutect2, varscan2
- SLX4 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV53568140; called by muse, mutect2, varscan2
- SMCHD1 | c.4108C>T p.R1370C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs942559171, COSV55255217; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SMYD2 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65291721; called by muse, mutect2, varscan2
- SNRPE | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 146/241 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV65843437; called by muse, mutect2, varscan2
- SNRPN | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.435); catalogued as rs1240777559, COSV57594131, COSV57601943; called by muse, mutect2, varscan2
- SNX29 | c.2200C>G p.R734G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100030598, COSV60069600; called by muse, mutect2, varscan2
- SORBS1 | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV53364588; called by muse, mutect2, varscan2
- SORCS1 | c.1940C>T p.T647I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs533738961, COSV53853029, COSV53897383; called by muse, mutect2, varscan2
- SPAM1 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV56147324; called by muse, mutect2, varscan2
- SPATA32 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as COSV59303963; called by muse, varscan2
- SPICE1 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV55624564; called by muse, mutect2, varscan2
- SPTA1 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 253/406 reads (62%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.926); catalogued as COSV63758592, COSV63760820; called by muse, mutect2, varscan2
- SPTBN4 | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 45/105 reads (43%) | catalogued as COSV58953256; called by muse, mutect2, varscan2
- ST13 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV53423612; called by muse, mutect2, varscan2
- STAB2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66346127; called by muse, mutect2, varscan2
- STAG2 | c.3533C>T p.S1178L | Missense Mutation (SNP) | VAF 132/145 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54370451, COSV54371414; called by muse, mutect2, varscan2
- STAT6 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440036653, COSV55666202, COSV55667826; called by muse, mutect2, varscan2
- STAT6 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100273430; called by muse, mutect2, varscan2
- STAU2 | c.581C>T p.S194L (on ENST00000524300 / NM_001164380.2; = p.S162L on NM_014393.2) | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV63311352; called by muse, mutect2, varscan2
- STC2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs1192348754, COSV99438540; called by muse, varscan2
- STXBP5L | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV56532805; called by muse, mutect2, varscan2
- STYXL2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs778182125, COSV54809628; called by muse, mutect2, varscan2
- SUGP2 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs200312727; called by muse, mutect2, varscan2
- SULT1A2 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs768403170, COSV57682993; called by muse, mutect2, varscan2
- SUPT6H | c.4054C>T p.Q1352* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100112599; called by muse, mutect2, varscan2
- SUPT6H | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs1350680093, COSV56386343; called by muse, mutect2, varscan2
- SV2C | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV59228120; called by muse, mutect2, varscan2
- SVOPL | c.1349C>T p.S450F (on ENST00000419765; = p.S298F on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1280533615, COSV55995096; called by muse, mutect2
- SYNPO | c.1622G>A p.R541K (on ENST00000394243 / NM_001166208.2; = p.R297K on NM_007286.6) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56942854; called by muse, mutect2, varscan2
- SYT17 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs756126766, COSV62546230; called by muse, mutect2, varscan2
- SZT2 | c.7162G>A p.E2388K (on ENST00000634258 / NM_001365999.1; = p.E2331K on NM_015284.4) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779077204, COSV100987288, COSV65174069; called by muse, mutect2, varscan2
- TACC2 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57771350; called by muse, mutect2, varscan2
- TAF3 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV60211135; called by muse, mutect2, varscan2
- TARS2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV64696800; called by muse, mutect2, varscan2
- TAS2R9 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.889); catalogued as rs115762530, COSV53690494; called by muse, mutect2, varscan2
- TBC1D15 | c.130-1G>A p.X44_splice | Splice Site (SNP) | VAF 51/133 reads (38%) | catalogued as rs763334828, COSV59852622; called by muse, mutect2, varscan2
- TBC1D24 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53548727; called by muse, mutect2, varscan2
- TBR1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67419104; called by muse, mutect2, varscan2
- TBX19 | c.666A>T p.R222S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV63198349; called by muse, mutect2, varscan2
- TCIM | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 67/85 reads (79%) | catalogued as COSV59928310; called by muse, mutect2, varscan2
- TCTN2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 117/486 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs1156772105, COSV57632602; called by muse, mutect2, varscan2
- TDRD6 | c.4363C>T p.Q1455* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | catalogued as COSV60176594; called by muse, mutect2, varscan2
- TEK | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV66233865; called by muse, mutect2, varscan2
- TENM1 | c.4522C>T p.L1508F | Missense Mutation (SNP) | VAF 94/112 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV64441720; called by muse, mutect2, varscan2
- TENM3 | c.3472A>G p.I1158V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.785); catalogued as COSV69317963; called by muse, mutect2, varscan2
- TENM3 | c.5788G>A p.E1930K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs747414557, COSV69317975; called by muse, mutect2
- TET1 | c.4894C>T p.P1632S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65389106; called by muse, mutect2, varscan2
- TEX14 | c.2731G>A p.E911K (on ENST00000240361 / NM_001201457.2; = p.E905K on NM_031272.5) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs1298414370, COSV53611338; called by muse, mutect2, varscan2
- TEX55 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as rs1006350518, COSV55212793; called by muse, mutect2, varscan2
- TG | c.3920G>A p.S1307N | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.296); catalogued as COSV55092510; called by muse, mutect2, varscan2
- TIMELESS | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765264874, COSV57510309; called by muse, mutect2, varscan2
- TINAGL1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99593015; called by muse, mutect2, varscan2
- TLR1 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764099685, COSV58305538; called by muse, mutect2, varscan2
- TMEM132B | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as rs773643411, COSV54768073; called by muse, mutect2, varscan2
- TMEM132D | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV70593364; called by muse, mutect2, varscan2
- TMEM54 | c.15C>T p.L5= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as COSV61276363; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59529435; called by muse, mutect2, varscan2
- TNFRSF9 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1216442025, COSV66349544; called by muse, mutect2, varscan2
- TNIP3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99284673; called by muse, mutect2, varscan2
- TNK1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1291742593, COSV61172399; called by muse, mutect2, varscan2
- TNN | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV53434436; called by muse, mutect2
- TNPO3 | c.604T>A p.F202I | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.688); catalogued as COSV55286320; called by muse, mutect2, varscan2
- TNXB | c.8935G>A p.E2979K (on ENST00000647633; = p.E2732K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/591 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); catalogued as COSV64488085; called by muse, mutect2, varscan2
- TOP2A | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV70733729; called by muse, mutect2, varscan2
- TOR1AIP2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV62625763; called by muse, mutect2, varscan2
- TP53BP1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55508074; called by muse, mutect2, varscan2
- TP53I13 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1008902741, COSV56403937; called by muse, mutect2, varscan2
- TPPP2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs185684452, COSV58794523; called by muse, mutect2, varscan2
- TPRG1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs759000542, COSV61463190; called by muse, mutect2, varscan2
- TRAT1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55467290; called by muse, mutect2, varscan2
- TRAV8-4 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs770208659; called by muse, mutect2, varscan2
- TRIM36 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs1480925074, COSV56693009; called by muse, mutect2, varscan2
- TRIM46 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100104614; called by muse, mutect2, varscan2
- TRIM46 | c.1884C>T p.P628= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as rs1218162317, COSV58113199; called by muse, mutect2, varscan2
- TRIM58 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV63572123; called by muse, mutect2, varscan2
- TRIML1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100205779, COSV60196705; called by muse, mutect2, varscan2
- TRIO | c.5579G>A p.G1860D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.457); catalogued as COSV60094348; called by muse, mutect2, varscan2
- TRPC3 | c.1559G>A p.G520E (on ENST00000379645 / NM_001366479.2; = p.G447E on NM_003305.2) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53380631; called by muse, mutect2, varscan2
- TRPC6 | c.2410-1G>A p.X804_splice | Splice Site (SNP) | VAF 15/17 reads (88%) | catalogued as COSV60260446; called by muse, mutect2, varscan2
- TRPM7 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); catalogued as COSV57921136; called by muse, mutect2, varscan2
- TSHB | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs121918669, CM900214, COSV56655389; called by muse, mutect2, varscan2
- TSHZ2 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.022); catalogued as COSV61588266; called by muse, mutect2, varscan2
- TSPAN14 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV55420461; called by muse, mutect2, varscan2
- TTC21B | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764002938, COSV99692586; called by muse, mutect2, varscan2
- TTC21B | c.1088-1G>A p.X363_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99692592; called by muse, mutect2, varscan2
- TTC3 | c.3155C>T p.S1052L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.261); catalogued as COSV100695203, COSV61295476; called by muse, mutect2, varscan2
- TTN | c.81758C>T p.S27253F (on ENST00000591111; = p.S19829F on NM_003319.4) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | PolyPhen benign (0.173); catalogued as COSV60311706; called by muse, mutect2, varscan2
- TTN | c.81316G>A p.E27106K (on ENST00000591111; = p.E19682K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | PolyPhen benign (0.443); catalogued as COSV60244623; called by muse, mutect2, varscan2
- TTN | c.55418C>T p.T18473I (on ENST00000591111; = p.T11049I on NM_003319.4) | Missense Mutation (SNP) | VAF 140/393 reads (36%) | PolyPhen benign (0.003); catalogued as COSV100588798, COSV60311893; called by muse, mutect2, varscan2
- TTN | c.52553G>A p.G17518D (on ENST00000591111; = p.G10094D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | PolyPhen probably damaging (1); catalogued as COSV60311938; called by muse, mutect2, varscan2
- TTN | c.38140G>A p.G12714R (on ENST00000591111; = p.G5290R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | PolyPhen benign (0.16); catalogued as rs1173986971, COSV60311990, COSV60386044; called by muse, mutect2, varscan2
- TTN | c.30580G>A p.E10194K (on ENST00000591111; = p.E9267K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | PolyPhen benign (0); catalogued as rs1238948061, COSV59883774; called by muse, mutect2, varscan2
- TUBA3D | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs756867847, COSV58313212; called by muse, varscan2
- TULP3 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as COSV68118664; called by muse, mutect2, varscan2
- TYR | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1001944031, COSV99634834; called by muse, mutect2, varscan2
- UBR4 | c.10968G>T p.E3656D | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV64398366; called by muse, mutect2, varscan2
- UGT1A7 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60830276; called by muse, mutect2, varscan2
- UGT2A2 | c.716G>A p.W239* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV54146071; called by muse, mutect2, varscan2
- UGT2B15 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57736374; called by muse, mutect2, varscan2
- UNC13C | c.6181C>T p.H2061Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as COSV52880692; called by muse, mutect2, varscan2
- UPB1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs367569283; called by muse, mutect2, varscan2
- UQCRC1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539038461, COSV52552936; called by muse, mutect2, varscan2
- UQCRFS1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV59185414; called by muse, mutect2, varscan2
- USH2A | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs372993160, COSV56428322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP6 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1177626442, COSV100003876, COSV51495213; called by muse, mutect2, varscan2
- VGLL4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750503637, COSV99810079; called by muse, mutect2, varscan2
- VGLL4 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763090675, COSV99810084; called by muse, mutect2, varscan2
- VIL1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV50295820; called by muse, mutect2, varscan2
- VPS13C | c.5618A>T p.D1873V (on ENST00000644861 / NM_020821.3; = p.D1830V on NM_017684.5) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV51422187; called by muse, mutect2, varscan2
- VPS13D | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1353961621, COSV62533964; called by muse, mutect2, varscan2
- WAPL | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV53939748; called by muse, mutect2, varscan2
- WDR11 | c.3292-1G>A p.X1098_splice | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as COSV54793137, COSV99676803; called by muse, mutect2, varscan2
- WDR11 | c.3292G>A p.V1098I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99676805; called by muse, mutect2, varscan2
- WDR19 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs764490726, COSV56466880; called by muse, mutect2, varscan2
- WDR49 | c.1240G>A p.E414K (on ENST00000308378 / NM_001366158.1; = p.E755K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57711432; called by muse, mutect2, varscan2
- WFDC1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1459470816, COSV54745627; called by muse, mutect2, varscan2
- WNT8B | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100649070; called by muse, mutect2, varscan2
- WNT8B | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1341009473, COSV100649072; called by muse, mutect2, varscan2
- ZAN | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.55); catalogued as rs758826727, COSV61815619; called by muse, mutect2, varscan2
- ZAN | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV61805735, COSV61809213; called by muse, mutect2, varscan2
- ZBTB34 | c.1345A>G p.K449E | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV59860778; called by muse, mutect2, varscan2
- ZCCHC14 | c.1967C>T p.S656F (on ENST00000268616; = p.S793F on NM_015144.3) | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV51890090; called by muse, mutect2, varscan2
- ZFHX3 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as COSV51711886, COSV51742992; called by muse, mutect2, varscan2
- ZFP90 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); catalogued as COSV68051326; called by muse, mutect2, varscan2
- ZFY | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 45/61 reads (74%) | catalogued as COSV50083907; called by muse, mutect2, varscan2
- ZFYVE9 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV55090874, COSV55099229; called by muse, mutect2, varscan2
- ZIM2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV55645807; called by muse, mutect2, varscan2
- ZIM3 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54146284; called by muse, mutect2, varscan2
- ZKSCAN1 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs759540374, COSV60872986; called by muse, mutect2, varscan2
- ZMAT4 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 146/191 reads (76%) | catalogued as COSV52712887; called by muse, mutect2, varscan2
- ZNF143 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs889416330, COSV55182435; called by muse, mutect2, varscan2
- ZNF17 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as COSV56922424; called by muse, mutect2, varscan2
- ZNF195 | c.461C>T p.T154I (on ENST00000399602 / NM_001130520.3; = p.T82I on NM_007152.5) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV50004385; called by muse, mutect2, varscan2
- ZNF200 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 135/343 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752359318, COSV67724100, COSV67724282; called by muse, mutect2, varscan2
- ZNF205 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV54622777; called by muse, mutect2, varscan2
- ZNF208 | c.3638G>A p.R1213K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV68104617; called by muse, mutect2, varscan2
- ZNF341 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV61011033; called by muse, mutect2, varscan2
- ZNF366 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1432849566, COSV59215035, COSV59218718; called by muse, mutect2
- ZNF445 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV68539564; called by muse, mutect2, varscan2
- ZNF530 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.965); catalogued as COSV60532218; called by muse, mutect2, varscan2
- ZNF550 | c.918T>A p.N306K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV57307301; called by muse, mutect2, varscan2
- ZNF559 | c.272T>A p.F91Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57837235; called by muse, mutect2, varscan2
- ZNF592 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV55439389; called by muse, mutect2, varscan2
- ZNF674 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV70379715; called by muse, mutect2, varscan2
- ZNF705A | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.302); catalogued as rs867282886, COSV63733217, COSV63733710; called by muse, mutect2, varscan2
- ZNF711 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52158634; called by muse, mutect2
- ZNF768 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63324140; called by muse, mutect2, varscan2
- ZNF804A | c.2944G>A p.G982R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); catalogued as COSV56469137; called by muse, mutect2, varscan2
- ZNF99 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV68055584, COSV68056605; called by muse, mutect2, varscan2
- ZNF99 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101233899, COSV68055559; called by muse, mutect2, varscan2
- ZSCAN10 | c.1747G>A p.E583K (on ENST00000252463; = p.E638K on NM_032805.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs540283059, COSV52970582, COSV99374112; called by muse, mutect2, varscan2
- ZSCAN32 | c.1156C>A p.Q386K (on ENST00000396846; = p.Q407K on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59236838, COSV59237067; called by muse, mutect2, varscan2
- ZSCAN5A | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs373832268; called by muse, mutect2, varscan2
450 further variants in this file (20 protein-altering or splice-affecting, 406 silent, 24 other) are not listed here.
